CPTAC case C3L-04081 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/03a973ea-08dd-42c1-9411-afcb831e660f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1954; Vital status: Dead; Days to death: 287 days; Year of death: 2019; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 63.6 years (23,222 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 287 days; Progression or recurrence: no; Days to last follow up: 287 days.
   Pathology details: Greatest tumor dimension: 2 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 287 days; Disease response: Progressive Disease; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 287 days; Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 93.89 kg; Height: 177.8 cm; BMI: 29.7.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04081-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 11 days; Initial weight: 24 mg; Time between excision and freezing: 25 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04081-21: Section location: Left Hemisphere; Percent tumor nuclei: 40; Percent necrosis: 10.
- Sample C3L-04081-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 11 days; Initial weight: 76 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04081-22: Section location: Left Hemisphere; Percent tumor nuclei: 35; Percent necrosis: 25.
- Sample C3L-04081-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 11 days; Initial weight: 26 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04081-23: Section location: Left Hemisphere; Percent tumor nuclei: 35; Percent necrosis: 25.
- Sample C3L-04081-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
